Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A3DS, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A3DS-01A (Primary Tumor).

	10/21/11	

AT 1004

9167

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

1. TOTAL THYROID

SPECIMEN TYPE:

Total thyroidectomy.

TUMOR SITE:

Right lobe.

HISTOLOGIC TYPE:

Papillary adenocarcinoma.

TUMOR SIZE:

Greatest dimension 0.8 cm

FOCALITY:

Unifocal

LYMPH NODES:

All 8 lymph nodes are negative for tumor.

EXTENT OF INVASION

PRIMARY TUMOR:

pT1: Tumor size <2 cm, limited to thyroid.

REGIONAL LYMPH NODES:

pNO: No regional lymph node metastasis.

DISTANT METASTASIS:

pMx: Cannot be assessed.

MARGINS:

Margins are uninvolved.

VENOUS/LYMPHATIC INVASION:

Absent

ADDITIONAL PATHOLOGIC FINDINGS:

Thyroiditis, Adenomatoid nodule (0.7 cm). Intraparenchymal parathyroid tissue (4mm) right lobe.

ICD-0-3

Carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9

10/21/11

Source: NCI Genomic Data Commons file 67c6e098-5cff-469b-9842-dbf5adb1cd3b (TCGA-ET-A3DS.7EFF2F11-7160-4259-904F-44D39C1C0243.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).